Somatic mutation profile of tumor specimen MP2PRT-PAUARG-TMP1-A (aliquot MP2PRT-PAUARG-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PAUARG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (696 days).
Specimen MP2PRT-PAUARG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cd45e60-ac74-46cc-9de1-5200063299f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUARG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUARG-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f783873-ea4f-4358-b3f2-6ac23d40d293

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1L1 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 113/479 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs950827145; called by muse, mutect2, varscan2
- GCN1 | c.7946G>A p.R2649Q | Missense Mutation (SNP) | VAF 126/441 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.186); catalogued as rs773861589; called by muse, mutect2, varscan2
- PSMA5 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99600579; called by muse, mutect2
- SLC43A3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs762938193; called by muse, mutect2, varscan2
- DLK1 | c.1007A>T p.N336I | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- E4F1 | c.1749_1750insATTCTCGGGGTTGGC p.G583_F584insILGVG | In Frame Ins (INS) | VAF 49/491 reads (10%) | called by mutect2, pindel
- ENPEP | c.2465G>T p.G822V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- FER1L6 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 147/513 reads (29%) | called by muse, mutect2, varscan2
- PKHD1 | c.8600C>A p.S2867Y | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PLEKHG2 | c.2368A>G p.I790V | Missense Mutation (SNP) | VAF 19/636 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- RAP2C | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 165/613 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF135 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- TJP1 | c.3682C>A p.P1228T | Missense Mutation (SNP) | VAF 284/611 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CAD | c.4761T>C p.I1587= | Silent (SNP) | VAF 97/345 reads (28%) | called by muse, mutect2, varscan2
- SALL3 | c.1974G>A p.T658= | Silent (SNP) | VAF 38/930 reads (4%) | catalogued as rs759576604, COSV73306329; called by muse, mutect2
- SLC44A5 | c.1038C>T p.L346= | Silent (SNP) | VAF 23/419 reads (5%) | catalogued as rs200333189; called by muse, mutect2
